Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3956, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3956-01A (Primary Tumor).

Diagnosis (diagnoses):

Resected ileocolic sample with a moderately differentiated adenocarcinoma of the colorectal type, located in the cecum, max. 4 cm in diameter, with infiltration of the pericecal fatty tissue. Circumscribed fibrinous serositis in the area of the tumor.

Stage of tumor: pT3, pN0 (0/36), pMX; G2, L0, V0, R0

Source: NCI Genomic Data Commons file 2a0c09c8-6cc9-4538-9d65-7fc23bd67834 (TCGA-AA-3956.9BBB5E1A-4BBB-4882-A294-E0F13D82FA4C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).